Somatic mutation profile of tumor specimen TCGA-AR-A250-01A (aliquot TCGA-AR-A250-01A-31D-A167-09) from TCGA case TCGA-AR-A250, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 58.3 years (21,309 days).
Specimen TCGA-AR-A250-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ad3cb09-4a2a-4936-99a6-a3560778b68c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A250-10A (Blood Derived Normal), aliquot TCGA-AR-A250-10A-01D-A167-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/703a2ead-b1a7-4932-85e3-e05c92a57af6

The open-access MAF lists 110 somatic variants for this specimen: 86 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 22, Nonsense Mutation 9, Frame Shift Ins 2, 3'UTR 1, In Frame Del 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC5 | c.4087G>C p.E1363Q | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV55587086; called by muse, mutect2, varscan2
- AC127029.3 | c.806C>G p.S269* | Nonsense Mutation (SNP) | VAF 21/184 reads (11%) | catalogued as COSV100033231, COSV60110868; called by muse, mutect2, varscan2
- AC136428.1 | c.59A>C p.E20A | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.463); catalogued as COSV101434961; called by muse, mutect2, varscan2
- ACAD8 | c.926T>C p.L309P | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55539033; called by muse, mutect2, varscan2
- ACADL | c.1218A>T p.R406S | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99284632; called by muse, mutect2
- ACADL | c.1217G>C p.R406T | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99284634; called by muse, mutect2
- ANGEL2 | c.848G>T p.R283I | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64736816; called by muse, mutect2, varscan2
- ANKRD11 | c.3172G>C p.E1058Q | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.69); catalogued as COSV56354768; called by muse, mutect2, varscan2
- ATAD2B | c.3850G>T p.E1284* | Nonsense Mutation (SNP) | VAF 5/62 reads (8%) | catalogued as COSV99477268; called by muse, mutect2
- C4orf51 | c.349G>C p.D117H | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.276); catalogued as COSV101439985; called by muse, mutect2
- CACNA1F | c.3301G>A p.E1101K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV59903020; called by muse, mutect2, varscan2
- CACNB1 | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV59998027; called by muse, mutect2, varscan2
- CANX | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV56002664, COSV56004146; called by muse, mutect2, varscan2
- CASP8AP2 | c.2545C>T p.H849Y | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV52745188; called by muse, mutect2, varscan2
- CFAP20DC | c.1274C>T p.P425L (on ENST00000482387 / NM_001351530.2; = p.P300L on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV55916112; called by muse, mutect2, varscan2
- CNTD1 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV55901473; called by muse, mutect2, varscan2
- CPXCR1 | c.307C>T p.H103Y | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV52161001; called by muse, mutect2, varscan2
- CRYBG3 | c.6529G>A p.D2177N | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.664); catalogued as COSV51709468, COSV99477338; called by muse, mutect2, varscan2
- DENND2C | c.2501C>G p.S834C (on ENST00000393274 / NM_001256404.2; = p.S777C on NM_198459.4) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67920047; called by muse, mutect2, varscan2
- DOCK1 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV99728144; called by mutect2, varscan2
- DOCK3 | c.2614G>C p.E872Q | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV56542553, COSV99810320; called by muse, mutect2
- DYNC1I1 | c.760G>C p.D254H | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100267934; called by muse, mutect2
- EDNRB | c.475G>A p.A159T (on ENST00000377211 / NM_001201397.1; = p.A69T on NM_000115.5) | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV57518944; called by muse, mutect2, varscan2
- EIF4G2 | c.823G>T p.D275Y | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60596156; called by muse, mutect2, varscan2
- F5 | c.4411C>G p.Q1471E | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.315); catalogued as COSV63120445; called by muse, mutect2, varscan2
- F5 | c.4100C>T p.S1367F | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.011); catalogued as COSV100889012, COSV63126758; called by muse, mutect2
- F5 | c.3397C>G p.Q1133E | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.3); catalogued as COSV100889013; called by muse, mutect2
- FAM160A2 | c.2525C>T p.A842V (on ENST00000449352 / NM_001098794.2; = p.A856V on NM_032127.4) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV56409496; called by muse, mutect2, varscan2
- FAM193A | c.1566G>C p.W522C | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61190872; called by muse, mutect2, varscan2
- FANCE | c.487C>G p.Q163E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV57689074; called by muse, mutect2, varscan2
- GLE1 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100012432; called by muse, mutect2
- KIAA1328 | c.122C>G p.S41* | Nonsense Mutation (SNP) | VAF 6/57 reads (11%) | catalogued as COSV54447437; called by muse, mutect2, varscan2
- KLB | c.1541C>T p.T514M | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.548); catalogued as rs745937646, COSV57300053; called by muse, mutect2, varscan2
- KNL1 | c.1479T>G p.D493E (on ENST00000346991 / NM_170589.5; = p.D467E on NM_144508.5) | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.391); catalogued as COSV100706164; called by muse, mutect2
- MAL2 | c.181C>G p.L61V | Missense Mutation (SNP) | VAF 17/200 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.248); catalogued as COSV99410945; called by muse, mutect2
- MAP1A | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55806072; called by muse, varscan2
- MTSS1 | c.252G>A p.M84I | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV100274623; called by muse, mutect2
- MUC15 | c.170C>G p.S57* | Nonsense Mutation (SNP) | VAF 9/159 reads (6%) | catalogued as COSV55552470, COSV99846292; called by muse, mutect2
- NEDD4 | c.1361G>A p.R454Q | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs919291836, COSV59058493; called by muse, mutect2, varscan2
- NLRP7 | c.2693C>T p.A898V (on ENST00000340844 / NM_206828.3; = p.A870V on NM_139176.3) | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs775039016, COSV60183296; called by muse, mutect2
- NUP155 | c.2551G>A p.A851T (on ENST00000231498 / NM_153485.3; = p.A792T on NM_004298.4) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs749163402, COSV51526797; called by muse, mutect2, varscan2
- OR5T2 | c.777G>C p.L259F | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57589427, COSV57590561; called by muse, mutect2
- P2RY1 | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV59308828; called by muse, mutect2, varscan2
- PARP8 | c.851C>G p.S284C | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.987); catalogued as COSV55855818, COSV55859989; called by muse, mutect2, varscan2
- PHLDB2 | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.018); catalogued as COSV67307974; called by muse, mutect2, varscan2
- POLR1A | c.2528G>A p.R843Q | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs762778123, COSV55689100, COSV99808547; called by muse, mutect2, varscan2
- PPOX | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs965557923, COSV57086702; called by muse, mutect2
- PRB4 | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.01); catalogued as rs765811780, COSV54395181; called by muse, varscan2
- RAPGEF1 | c.3220G>A p.E1074K | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.524); catalogued as COSV100940389; called by muse, mutect2, varscan2
- RASGRP1 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.727); catalogued as rs1200829567, COSV60363673; called by muse, mutect2
- ROR1 | c.748G>C p.D250H | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV64283859, COSV64286071; called by muse, mutect2, varscan2
- RPL10L | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.103); catalogued as rs562526716, COSV53558633; called by mutect2, varscan2
- RPL8 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV52800293, COSV99068717; called by muse, mutect2
- RPS6KA5 | c.1575G>T p.M525I | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.519); catalogued as COSV56219414; called by muse, mutect2, varscan2
- SATB1 | c.1576G>A p.G526R | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100113022; called by muse, mutect2
- SH3RF1 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs1470725365, COSV52924206; called by mutect2, varscan2
- SHISA5 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV56498740; called by muse, mutect2, varscan2
- SLC13A5 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs201674669, COSV53421201; called by muse, mutect2, varscan2
- SLC7A9 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as rs1294879564, COSV99195241; called by muse, mutect2
- SLC8A1 | c.1852A>G p.K618E | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV60470860; called by muse, varscan2
- SMIM7 | c.196del p.M66Cfs*4 | Frame Shift Del (DEL) | VAF 12/59 reads (20%) | catalogued as COSV62417679; called by mutect2, pindel, varscan2
- SPAST | c.1300C>T p.Q434* | Nonsense Mutation (SNP) | VAF 8/109 reads (7%) | catalogued as CM022251; called by muse, mutect2
- SPATA31A3 | c.3574dup p.T1192Nfs*14 | Frame Shift Ins (INS) | VAF 43/120 reads (36%) | catalogued as rs1301154937; called by mutect2, pindel, varscan2
- SPDL1 | c.272T>A p.L91Q | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54666964; called by muse, mutect2, varscan2
- SUOX | c.1397G>T p.G466V | Missense Mutation (SNP) | VAF 12/199 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99906983; called by muse, mutect2
- TBC1D1 | c.970C>T p.Q324* | Nonsense Mutation (SNP) | VAF 9/76 reads (12%) | catalogued as COSV54714117; called by muse, mutect2, varscan2
- TBC1D8B | c.3010C>G p.H1004D | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs758383959, COSV52175850, COSV52176230; called by muse, mutect2, varscan2
- TDP2 | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 14/144 reads (10%) | catalogued as COSV100593603; called by muse, mutect2, varscan2
- TEX10 | c.2351A>T p.D784V | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100887661; called by muse, mutect2, varscan2
- TEX10 | c.1396G>C p.E466Q | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.462); catalogued as rs1462885915, COSV100887662, COSV100887937; called by muse, mutect2, varscan2
- TMEM71 | c.16C>G p.Q6E | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.291); catalogued as COSV63458059; called by muse, mutect2
- TNR | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1221706569, COSV54870365; called by muse, mutect2, varscan2
- TRIM38 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.173); catalogued as rs1266712951, COSV62641678; called by muse, mutect2
- UBE4B | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs760809804, COSV53527110; called by muse, mutect2, varscan2
- UBXN2A | c.83A>G p.N28S | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV58335668; called by muse, mutect2, varscan2
- UNC13A | c.3721G>T p.A1241S | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1385374269, COSV53188337; called by muse, mutect2, varscan2
- VPS13B | c.2963T>G p.M988R | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.029); catalogued as COSV100661392; called by muse, mutect2
- XRRA1 | c.925G>C p.D309H | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as COSV58496150, COSV58497462; called by muse, mutect2, varscan2
- ZC3H15 | c.586T>G p.W196G | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as COSV61921739; called by muse, mutect2
- ZEB2 | c.270G>T p.E90D | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV100355555; called by muse, mutect2, varscan2
- ZHX2 | c.1216A>G p.K406E | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV100072772; called by muse, mutect2
- ZNF510 | c.1681C>G p.Q561E | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.33); catalogued as COSV99793800; called by muse, mutect2
- MYO3A | c.2233_2235del p.Y745del | In Frame Del (DEL) | VAF 4/42 reads (10%) | called by pindel, varscan2
- PRAMEF19 | c.1280C>A p.S427* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- SDK2 | c.3438_3442dup p.L1148Rfs*3 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by mutect2, pindel
- TOPORS | c.1897G>T p.E633* | Nonsense Mutation (SNP) | VAF 6/148 reads (4%) | called by muse, mutect2
- CARD9 | c.1371C>T p.G457= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs751319751, COSV59996236; called by muse, mutect2, varscan2
- DCDC1 | c.5277G>A p.Q1759= (on ENST00000597505 / NM_001367979.1; = p.Q866= on NM_020869.3) | Silent (SNP) | VAF 9/95 reads (9%) | catalogued as COSV100360389; called by muse, mutect2
- FAM184A | c.1665C>G p.L555= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV58851631; called by muse, mutect2, varscan2
- GNA14 | c.351C>G p.V117= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV59018609, COSV59029475; called by muse, mutect2, varscan2
- GSDMC | c.594C>G p.L198= | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as rs1256208465, COSV52693167; called by muse, mutect2, varscan2
- HTR1A | c.534G>A p.P178= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV60500021, COSV60501567; called by muse, mutect2
- IQGAP2 | c.3828C>A p.T1276= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV57178368, COSV99166871; called by muse, mutect2
- KCNN3 | c.273C>G p.L91= | Silent (SNP) | VAF 9/92 reads (10%) | catalogued as COSV99677882; called by muse, mutect2
- KIAA1217 | c.135A>G p.E45= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV64600493; called by muse, mutect2, varscan2
- LINS1 | c.237C>T p.N79= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV59077867; called by muse, mutect2, varscan2
- LIPK | c.1044C>G p.P348= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV68200596; called by muse, mutect2, varscan2
- LRP8 | c.2730C>T p.T910= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV60096045; called by muse, mutect2, varscan2
- MCUR1 | c.1038G>A p.T346= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as rs572372696, COSV64846599; called by muse, mutect2, varscan2
- NTRK1 | c.2085G>A p.P695= | Silent (SNP) | VAF 14/16 reads (88%) | catalogued as rs377730927, COSV100693306; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR4X1 | c.156G>T p.V52= | Silent (SNP) | VAF 22/130 reads (17%) | catalogued as COSV60722239; called by muse, mutect2, varscan2
- OR6K6 | c.489C>T p.I163= (on ENST00000368144; = p.I139= on NM_001005184.1) | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV100933711; called by muse, mutect2
- ROPN1B | c.177C>T p.V59= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as rs541348602, COSV52541687; called by muse, mutect2, varscan2
- SPTA1 | c.852A>G p.E284= | Silent (SNP) | VAF 24/42 reads (57%) | catalogued as COSV63748939; called by muse, mutect2, varscan2
- TEX2 | c.1620T>C p.D540= | Silent (SNP) | VAF 12/168 reads (7%) | catalogued as COSV99366913; called by muse, mutect2
- USP34 | c.6507C>T p.I2169= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV68398033; called by muse, mutect2, varscan2
- WDR59 | c.1410G>T p.L470= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV50933196; called by muse, mutect2, varscan2
- WNT2B | c.453C>A p.V151= (on ENST00000369684 / NM_024494.3; = p.V132= on NM_004185.4) | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as COSV56672372; called by muse, mutect2, varscan2
- FAM174A | c.*1G>C | 3'UTR (SNP) | VAF 5/42 reads (12%) | catalogued as COSV100444209; called by muse, mutect2, varscan2
- THSD4 | c.1016-69993C>G | Intron (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
